Gene-level copy-number profile of tumor specimen TCGA-HU-A4H0-01A from TCGA case TCGA-HU-A4H0, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.1 years (26,317 days).
Specimen TCGA-HU-A4H0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.c63d1be9-c7ee-4255-9458-f79dfe606998.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HU-A4H0-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 353 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/44efeec6-8fda-457c-baa3-449331a06dd0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3,613; copy number 1: 18,489; copy number 2: 18,766; copy number 3: 14,421; copy number 4: 2,781; copy number 5: 1,810; copy number 7: 6; copy number 8: 243; copy number 9: 126; copy number 10: 15.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HU-A4H0-01A-11D-A253-01): tumor purity 0.33, ploidy 1.98, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 1,227 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:204,545,475–205,620,162, 1 gene (within-gene range 0–3): PARD3B.
- chr2:205,253,304–205,253,503, 1 gene: AC008171.1.
- chr4:112,818,032–113,384,221, 1 gene (within-gene range 0–1): ANK2.
- chr4:113,106,863–133,575,208, 218 genes (broad region; genes not listed).
- chr4:181,237,358–190,092,279, 181 genes (broad region; genes not listed).
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr12:9,480,608–9,576,275, 2 genes: AC092821.1, AC092821.2.
- chr15:19,878,555–23,447,243, 169 genes (broad region; genes not listed).
- chr17:142,789–17,423,704, 653 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,200 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:137,995,270–137,996,147, 1 gene, copy number 5: RPSAP42.
- chr7:152,925,233–153,748,986, 6 genes, copy number 7: AC006348.1, AC079809.1, LINC01287, AC073236.1, PAXBP1P1, AC005998.1.
- chr9:14,475–29,636,853, 384 genes, copy number 8–10 (broad region; genes not listed).
- chr17:22,671,433–52,535,701, 1,208 genes, copy number 5 (broad region; genes not listed).
- chr19:27,638,483–28,125,430, 15 genes, copy number 5: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1.
- chr20:87,250–24,226,013, 484 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:49,293,394–55,744,938, 102 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 17,934. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
